Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6DN, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6DN-01B (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma NOS
8140/3
Site Middle third of
esophagus NOS C15.4
JW 5/21/13

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) ESOPHAGUS (BIOPSY OF MASS IN MID ESOPHAGUS AT 25 CENTIMETERS):
INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA.
See Comment section below.
- (B) ESOPHAGUS (BIOPSY OF POSSIBLE BARRETT'S ESOPHAGUS, SITE NOT OTHERWISE SPECIFIED):
INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA WITH ADJOINING AND SEPARATE HIGH-GRADE
COLUMNAR EPITHELIAL DYSPLASIA.
Separate cardiac-type mucosa with chronic inflammation and edema.
No intestinal metaplasia, including Barrett mucosa of the distinctive intestinalized type, or Helicobacter pylori identified.
See Comment section below.

COMMENT

The biopsy specimens from the esophageal mass (Part A) have sheets of poorly differentiated tumor cells without gland formation. Scattered mucin vacuoles are present on periodic acid-Schiff/Alcian blue stain. Immunohistochemistry has the following results for tumor cells:

Cdx2: Negative
Chromogranin: Negative
Synaptophysin: Negative
Pan-melanoma: Negative

The biopsy specimens from Part B are not described in the esophagogastroduodenoscopy procedure note in . The high-grade columnar epithelial dysplasia may be present in Barrett mucosa if the specimen was obtained from the esophagus.

GROSS DESCRIPTION

- (A) ESOPHAGEAL MASS AT 25 CM – Consists of multiple friable white-tan soft tissue fragments aggregating to 1.5 x 0.1 x 0.1 cm. Specimen submitted entirely in A.
- (B) POSSIBL BARRETT'S ESOPHAGUS – Consists of multiple friable, pale pink soft tissue fragments aggregating to 2 x 0.2 x 0.1 cm. Specimen submitted entirely in B.

CLINICAL HISTORY

Esophageal mass

SNOMED CODES

T-56000, M-81403, M-Y4030, M-43000

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

This report is issued to report immunohistochemistry results. Immunohistochemical stain for Her2-neu (is performed in our lab on a representative formalin fixed paraffin embedded section of adenocarcinoma in mid esophagus, Block: A1.

Staining	Score	Interpretation
No membranous staining of the invasive tumor cells	0	Negative

FOOTNOTE:

For Her 2: Positive cases are defined as those with strong complete, basolateral, or lateral membranous reactivity in $\geq 10\%$ of invasive tumor cells in resection specimen or strong complete, basolateral, or lateral membranous reactivity in any invasive tumor cells in biopsy specimen (Score 3+). Negative cases are defined as those with no staining (Score 0) or faint or barely perceptible membranous staining (Score 1+) of the invasive tumor cells. Equivocal cases are defined as those with weak to moderate complete, basolateral or lateral membranous reactivity in $\geq 10\%$ of invasive tumor cells in resection specimen or weak to moderate complete, basolateral or lateral membranous reactivity in any invasive tumor cells in biopsy specimen (Score 2+).

Reference Hofmann M, Stoss O, Shi D et al. Assessment of a HER2 scoring system for gastric cancer: results from a validation Study. Histopathology. 2008;52(7):797-805.

Entire report and diagnosis completed by:

—————END OF REPORT—————

Yes	No
	☒
	☒
	☒
	☒
	☒
Qualifies	Disqualified

Source: NCI Genomic Data Commons file 0a95fd4f-bb41-407d-8776-846fcd47ccd7 (TCGA-R6-A6DN.5C039D7B-55B0-44F3-97C2-56BA41946F38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).